Somatic mutation profile of tumor specimen C3L-05262-02 (aliquot CPT0282540011) from CPTAC case C3L-05262, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.7 years (19,625 days).
Specimen C3L-05262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac241980-7a79-4085-9af4-ecab7642d17c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05262-31 (Blood Derived Normal), aliquot CPT0282690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d211d9b-a71e-4714-b037-295f2a1a9509

The open-access MAF lists 176 somatic variants for this specimen: 120 protein-altering or splice-affecting, 51 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 51, Intron 4, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 316/408 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKUB1 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 197/547 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1002537688; called by muse, mutect2, varscan2
- APOB | c.2522G>A p.G841E | Missense Mutation (SNP) | VAF 204/576 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245396413, COSV99268724; called by muse, mutect2, varscan2
- ASTN1 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 401/703 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99922731; called by muse, mutect2, varscan2
- B3GALT1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 204/555 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs767958450, COSV59908508; called by muse, mutect2, varscan2
- BAZ2A | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 207/598 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs559622114, COSV51637400; called by muse, mutect2, varscan2
- C6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54706408; called by muse, mutect2, varscan2
- C8orf34 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV57414521; called by muse, mutect2, varscan2
- CACNA1E | c.6380C>T p.S2127L (on ENST00000367573 / NM_001205293.3; = p.S2084L on NM_000721.4) | Missense Mutation (SNP) | VAF 114/565 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV62429786; called by muse, mutect2, varscan2
- CCDC170 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 93/164 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53344296; called by muse, mutect2, varscan2
- CFAP100 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 189/504 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs747219927; called by muse, mutect2, varscan2
- COL28A1 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 159/406 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101258803, COSV101258827; called by muse, mutect2, varscan2
- CSF3R | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 258/718 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs147017250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.4781G>A p.G1594E (on ENST00000297405 / NM_001363185.1; = p.G1490E on NM_052900.3) | Missense Mutation (SNP) | VAF 252/506 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV52192913, COSV52193853; called by muse, mutect2, varscan2
- CWC27 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs568150813, COSV66884329; called by muse, mutect2, varscan2
- DHDDS | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 136/457 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV52575774, COSV52577228; called by muse, mutect2, varscan2
- DSG4 | c.2499G>A p.M833I | Missense Mutation (SNP) | VAF 353/668 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57390418; called by muse, mutect2, varscan2
- ERICH3 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 224/644 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV58612821; called by muse, mutect2, varscan2
- ERICH3 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 180/554 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs74543698, COSV100444109; called by muse, mutect2, varscan2
- FAM71E2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 144/464 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs1485889706, COSV52773468; called by muse, mutect2, varscan2
- FBN3 | c.6538C>T p.R2180C | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138756263, COSV54456109; called by muse, mutect2, varscan2
- FOXD4L5 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 406/1181 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs781582393, COSV101073104, COSV66241318; called by muse, mutect2, varscan2
- H2AZ2 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 163/551 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56063101; called by muse, mutect2, varscan2
- HDLBP | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 178/495 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100191525; called by muse, mutect2, varscan2
- HEPHL1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 171/482 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59894899; called by muse, mutect2, varscan2
- HYDIN | c.12241G>A p.E4081K | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs781242720, COSV66643032; called by muse, mutect2, varscan2
- JAKMIP2 | c.2318G>A p.R773K | Missense Mutation (SNP) | VAF 139/363 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV54602797; called by muse, mutect2, varscan2
- KERA | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 170/568 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57130737; called by muse, mutect2, varscan2
- LILRB1 | c.2045C>T p.P682L (on ENST00000427581; = p.P631L on NM_006669.6) | Missense Mutation (SNP) | VAF 234/776 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs1221829910, COSV61121305; called by muse, mutect2
- LILRB5 | c.1339G>A p.G447R (on ENST00000449561 / NM_001081442.3; = p.G446R on NM_006840.5) | Missense Mutation (SNP) | VAF 249/709 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1219109289; called by muse, mutect2, varscan2
- MAP2K7 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 187/485 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as rs775112625, COSV67607944; called by muse, mutect2, varscan2
- MUC5B | c.12041G>A p.R4014Q | Missense Mutation (SNP) | VAF 164/795 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as rs765255074, COSV101500092; called by muse, varscan2
- MYO15A | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 215/610 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1314383043, COSV52754013; called by muse, mutect2, varscan2
- MYT1L | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV67725856, COSV67733816; called by muse, mutect2, varscan2
- OR52N2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 186/619 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs897408821; called by muse, mutect2
- PAK5 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 181/516 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62023868; called by muse, mutect2, varscan2
- PCDHB11 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 321/962 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100696895; called by muse, mutect2, varscan2
- ROBO3 | c.3922G>A p.V1308M | Missense Mutation (SNP) | VAF 199/540 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs752717878, COSV60624157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 167/455 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV54214184; called by muse, mutect2, varscan2
- SLC8A3 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 200/528 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100775899; called by muse, mutect2, varscan2
- SOST | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 191/556 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs776670653; called by muse, mutect2, varscan2
- SPEG | c.7747C>T p.P2583S | Missense Mutation (SNP) | VAF 142/392 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV56681952; called by muse, mutect2, varscan2
- SYT4 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs768842434; called by muse, mutect2, varscan2
- TENM2 | c.5602A>C p.T1868P (on ENST00000518659 / NM_001122679.2; = p.T1629P on NM_001080428.3) | Missense Mutation (SNP) | VAF 207/595 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV69128779; called by muse, mutect2, varscan2
- TMPRSS11B | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 174/470 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs150665678; called by muse, mutect2, varscan2
- TNR | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 652/1073 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs551588483, COSV54878271; called by muse, mutect2, varscan2
- UBQLNL | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 156/498 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV66493562, COSV66493838; called by muse, mutect2, varscan2
- UGGT1 | c.2843T>G p.M948R | Missense Mutation (SNP) | VAF 147/397 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1178452218; called by muse, mutect2, varscan2
- UGT2B4 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as rs1560436615, COSV59315946; called by muse, mutect2, varscan2
- USP29 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 143/413 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as COSV99518830; called by muse, mutect2, varscan2
- WDR33 | c.3163C>T p.P1055S | Missense Mutation (SNP) | VAF 279/762 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.968); catalogued as rs777072307, COSV59247163; called by muse, mutect2, varscan2
- WDR87 | c.8404C>T p.R2802W | Missense Mutation (SNP) | VAF 196/523 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531892233, COSV58195781; called by muse, mutect2, varscan2
- WDR87 | c.6802G>A p.E2268K | Missense Mutation (SNP) | VAF 196/593 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.198); catalogued as rs1335699671; called by mutect2, varscan2
- ACTRT2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 238/705 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- BRWD1 | c.3113C>A p.S1038Y | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by mutect2, varscan2
- CEMIP | c.2594G>A p.R865K | Missense Mutation (SNP) | VAF 136/494 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CERS3 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 159/309 reads (51%) | called by muse, mutect2, varscan2
- CHEK1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHSY3 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 162/468 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLEC19A | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 158/438 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNFN | c.110T>A p.V37D | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DNAH9 | c.6611-1G>A p.X2204_splice | Splice Site (SNP) | VAF 63/213 reads (30%) | called by muse, mutect2, varscan2
- FAHD2A | c.875T>A p.F292Y | Missense Mutation (SNP) | VAF 164/467 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FAT1 | c.3967C>T p.L1323F | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FGF14 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 42/641 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); called by muse, mutect2
- FLG2 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 204/974 reads (21%) | called by muse, mutect2, varscan2
- FOXP4 | c.1313C>A p.A438D (on ENST00000307972 / NM_001012426.1; = p.A425D on NM_138457.3) | Missense Mutation (SNP) | VAF 265/840 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- G6PC3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 179/495 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- GIMAP5 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 377/489 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIPC3 | c.3314C>T p.S1105F | Missense Mutation (SNP) | VAF 117/307 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GNAS | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 231/1057 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- HENMT1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 169/560 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- HIP1R | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 167/396 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HNRNPF | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 108/517 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGDCC4 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 246/541 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- KIF2B | c.1770G>T p.E590D | Missense Mutation (SNP) | VAF 141/436 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHDC8B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 253/607 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP6 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 121/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 252/760 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MAP1B | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 151/434 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAU2 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 134/416 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MKRN2 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 196/559 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.5459C>A p.S1820Y | Missense Mutation (SNP) | VAF 197/622 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MUSK | c.1910A>C p.N637T | Missense Mutation (SNP) | VAF 227/342 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH6 | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 175/460 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR8G1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 131/463 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- P2RY8 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 305/805 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PAX7 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF21B | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 203/541 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PMAIP1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 188/740 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PRR5 | c.742C>T p.P248S (on ENST00000336985 / NM_181333.4; = p.P239S on NM_015366.4) | Missense Mutation (SNP) | VAF 183/544 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PTPRN2 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 206/950 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- QRICH1 | c.2148T>A p.S716R | Missense Mutation (SNP) | VAF 154/411 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RAP1GAP2 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 185/534 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REPS2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 180/266 reads (68%) | SIFT tolerated (0.34); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RFPL4AL1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 97/576 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RGPD4 | c.1508A>T p.K503I | Missense Mutation (SNP) | VAF 161/508 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SCUBE3 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 290/644 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SDC3 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 251/738 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSM3 | c.1902G>A p.R634= | Splice Region (SNP) | VAF 163/487 reads (33%) | called by muse, mutect2, varscan2
- SH2D4B | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 142/463 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SH3BP4 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 187/555 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3D21 | c.792G>T p.K264N (on ENST00000453908 / NM_001162530.2; = p.K153N on NM_024676.5) | Missense Mutation (SNP) | VAF 158/440 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIM1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A8 | c.1132A>G p.R378G | Missense Mutation (SNP) | VAF 186/533 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC26A8 | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 185/615 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SVEP1 | c.7037C>T p.T2346I | Missense Mutation (SNP) | VAF 88/431 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SYNCRIP | c.745T>G p.S249A | Missense Mutation (SNP) | VAF 142/267 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SYNE1 | c.15624T>G p.D5208E (on ENST00000367255 / NM_182961.4; = p.D5137E on NM_033071.3) | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SYT9 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 161/445 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TNRC6B | c.3378G>A p.M1126I (on ENST00000454349 / NM_001162501.2; = p.M1073I on NM_015088.3) | Missense Mutation (SNP) | VAF 141/401 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRHR | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 70/641 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TTC29 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 174/574 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- URI1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- XIRP2 | c.7603G>A p.V2535I (on ENST00000628543; = p.V2710I on NM_152381.6) | Missense Mutation (SNP) | VAF 156/471 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- XPO5 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZBTB16 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 224/644 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZNF654 | c.2740A>T p.T914S | Missense Mutation (SNP) | VAF 165/461 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF654 | c.2741C>T p.T914I | Missense Mutation (SNP) | VAF 165/462 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF722P | c.1110A>T p.K370N | Missense Mutation (SNP) | VAF 172/330 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM7 | c.1944G>A p.Q648= | Silent (SNP) | VAF 173/313 reads (55%) | called by muse, mutect2, varscan2
- ALPL | c.144C>T p.T48= | Silent (SNP) | VAF 165/426 reads (39%) | catalogued as COSV100876901; called by muse, mutect2, varscan2
- AURKB | c.405C>T p.P135= | Silent (SNP) | VAF 152/470 reads (32%) | catalogued as COSV100298718; called by muse, varscan2
- BAALC | c.528G>A p.K176= (on ENST00000297574 / NM_001364874.1; = p.K141= on NM_024812.3) | Silent (SNP) | VAF 223/440 reads (51%) | catalogued as COSV52565409; called by muse, mutect2, varscan2
- BAHD1 | c.468C>T p.D156= | Silent (SNP) | VAF 348/749 reads (46%) | catalogued as rs1173088934; called by muse, mutect2, varscan2
- CACNA1H | c.6240C>T p.S2080= | Silent (SNP) | VAF 279/737 reads (38%) | catalogued as rs1567558805; called by muse, mutect2, varscan2
- CARD6 | c.2562C>T p.S854= | Silent (SNP) | VAF 201/562 reads (36%) | catalogued as rs1345365990; called by muse, mutect2, varscan2
- CARNMT1 | c.480C>T p.S160= | Silent (SNP) | VAF 286/431 reads (66%) | catalogued as rs1414347437; called by muse, mutect2, varscan2
- CDH7 | c.1500C>T p.I500= | Silent (SNP) | VAF 108/445 reads (24%) | catalogued as COSV59893236; called by muse, mutect2, varscan2
- CEACAM7 | c.393G>A p.V131= | Silent (SNP) | VAF 156/435 reads (36%) | catalogued as COSV50073724; called by muse, mutect2, varscan2
- CEL | c.2046C>T p.P682= (on ENST00000673714; = p.P679= on NM_001807.6) | Silent (SNP) | VAF 99/334 reads (30%) | catalogued as rs760758682; called by muse, varscan2
- CHST10 | c.771G>A p.G257= | Silent (SNP) | VAF 199/540 reads (37%) | called by muse, mutect2, varscan2
- COL5A1 | c.3483C>T p.I1161= | Silent (SNP) | VAF 348/486 reads (72%) | catalogued as rs576483507; called by muse, mutect2, varscan2
- COL7A1 | c.6366T>C p.N2122= | Silent (SNP) | VAF 219/558 reads (39%) | catalogued as rs1269735258; called by muse, mutect2, varscan2
- DERA | c.111C>T p.T37= | Silent (SNP) | VAF 80/347 reads (23%) | catalogued as rs201344317; called by muse, mutect2, varscan2
- DMWD | c.1803C>T p.I601= | Silent (SNP) | VAF 179/531 reads (34%) | catalogued as rs781640052, COSV52174892; called by muse, mutect2, varscan2
- DNAL4 | c.279C>T p.F93= | Silent (SNP) | VAF 152/521 reads (29%) | catalogued as rs1448408794; called by muse, mutect2, varscan2
- DOP1A | c.3972C>T p.F1324= | Silent (SNP) | VAF 176/319 reads (55%) | catalogued as COSV52709265; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.747G>A p.R249= | Silent (SNP) | VAF 201/570 reads (35%) | catalogued as rs909435465, COSV62571200; called by muse, mutect2, varscan2
- FAT4 | c.11016C>T p.S3672= | Silent (SNP) | VAF 176/543 reads (32%) | catalogued as COSV58709632; called by muse, mutect2, varscan2
- GOLGA8R | c.801G>A p.K267= | Silent (SNP) | VAF 81/1334 reads (6%) | called by muse, mutect2
- GTPBP4 | c.1084C>T p.L362= | Silent (SNP) | VAF 113/340 reads (33%) | called by muse, mutect2, varscan2
- HDAC9 | c.1425G>A p.Q475= | Silent (SNP) | VAF 63/338 reads (19%) | called by muse, mutect2, varscan2
- LRFN2 | c.1905G>A p.L635= | Silent (SNP) | VAF 241/763 reads (32%) | catalogued as rs1237075246; called by muse, mutect2, varscan2
- LRIT1 | c.1621C>T p.L541= | Silent (SNP) | VAF 197/578 reads (34%) | catalogued as rs775990232; called by muse, mutect2, varscan2
- MBLAC1 | c.663G>T p.L221= | Silent (SNP) | VAF 126/933 reads (14%) | called by muse, mutect2, varscan2
- MMP1 | c.447C>T p.F149= | Silent (SNP) | VAF 160/430 reads (37%) | called by muse, mutect2, varscan2
- MYLK | c.171G>A p.R57= | Silent (SNP) | VAF 140/431 reads (32%) | called by muse, mutect2, varscan2
- NBEA | c.2064G>A p.L688= | Silent (SNP) | VAF 72/202 reads (36%) | called by muse, mutect2, varscan2
- OR51B5 | c.483C>T p.L161= | Silent (SNP) | VAF 135/357 reads (38%) | catalogued as COSV56175831; called by muse, mutect2, varscan2
- OR51I2 | c.135C>T p.I45= | Silent (SNP) | VAF 166/525 reads (32%) | catalogued as COSV58298957; called by muse, mutect2, varscan2
- OR6M1 | c.60G>A p.E20= | Silent (SNP) | VAF 172/492 reads (35%) | catalogued as COSV58433233; called by muse, mutect2, varscan2
- OR8G1 | c.417G>A p.K139= | Silent (SNP) | VAF 136/468 reads (29%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2193C>T p.P731= | Silent (SNP) | VAF 196/704 reads (28%) | catalogued as COSV50619504; called by muse, mutect2, varscan2
- PCDHB4 | c.1056C>T p.T352= | Silent (SNP) | VAF 165/454 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.537C>T p.S179= | Silent (SNP) | VAF 236/751 reads (31%) | catalogued as rs775303289, COSV53893411; called by muse, mutect2
- PCED1B | c.804G>A p.K268= | Silent (SNP) | VAF 218/628 reads (35%) | called by mutect2, varscan2
- PSG3 | c.705C>T p.L235= | Silent (SNP) | VAF 148/421 reads (35%) | called by muse, mutect2, varscan2
- SCARA3 | c.831G>A p.K277= | Silent (SNP) | VAF 219/416 reads (53%) | called by muse, mutect2, varscan2
- SCN10A | c.2757C>T p.V919= | Silent (SNP) | VAF 192/538 reads (36%) | catalogued as COSV101479505; called by muse, mutect2, varscan2
- SCN1A | c.5019C>T p.I1673= (on ENST00000303395 / NM_001202435.3; = p.I1662= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 205/672 reads (31%) | catalogued as rs757002972, COSV57679163; called by muse, mutect2, varscan2
- SCTR | c.60C>T p.C20= | Silent (SNP) | VAF 79/475 reads (17%) | called by muse, mutect2, varscan2
- SEMA3E | c.1455C>T p.F485= | Silent (SNP) | VAF 131/270 reads (49%) | called by muse, mutect2, varscan2
- SF3B3 | c.2112C>T p.V704= | Silent (SNP) | VAF 74/265 reads (28%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1080C>T p.F360= | Silent (SNP) | VAF 132/339 reads (39%) | catalogued as rs140306596; called by muse, mutect2, varscan2
- SMC1B | c.93C>T p.I31= | Silent (SNP) | VAF 121/374 reads (32%) | catalogued as rs1214047103, COSV61581908; called by muse, mutect2, varscan2
- TCF4 | c.1578G>A p.T526= | Silent (SNP) | VAF 167/752 reads (22%) | catalogued as rs774527851, COSV61895509; called by muse, mutect2, varscan2
- TRAPPC2B | c.135T>G p.A45= | Silent (SNP) | VAF 280/779 reads (36%) | called by muse, mutect2, varscan2
- TSBP1 | c.1584G>A p.K528= (on ENST00000617061; = p.K533= on NM_006781.5) | Silent (SNP) | VAF 220/762 reads (29%) | catalogued as COSV100898801; called by muse, mutect2, varscan2
- TTN | c.9813C>T p.S3271= (on ENST00000591111; = p.S3225= on NM_003319.4) | Silent (SNP) | VAF 193/546 reads (35%) | called by muse, mutect2, varscan2
- WIZ | c.537G>A p.Q179= | Silent (SNP) | VAF 142/403 reads (35%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179483C>T | Intron (SNP) | VAF 244/734 reads (33%) | catalogued as rs1415245315; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1762C>T | 3'UTR (SNP) | VAF 147/403 reads (36%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27594C>T | Intron (SNP) | VAF 76/246 reads (31%) | catalogued as rs1332693896; called by muse, mutect2, varscan2
- PXN | c.934-66C>T | Intron (SNP) | VAF 184/554 reads (33%) | called by muse, mutect2, varscan2
- RBM46 | c.1403-1097C>T | Intron (SNP) | VAF 100/298 reads (34%) | called by muse, mutect2, varscan2
